TCGA case TCGA-24-1463 — Ovarian Serous Cystadenocarcinoma (TCGA-OV)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Ovary; Tissue source site: Washington University. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/171f7917-69eb-4a3f-9cc0-0e1dffd412c1

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 70 years; Vital status: Dead; Days to death: 2,218 days (6.1 years).

Diagnoses (2)
1. Serous cystadenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8441/3; ICD-10 code: C56.9; Tissue or organ of origin: Ovary; Site of resection or biopsy: Ovary; Laterality: Bilateral; Classification of tumor: primary; Age at diagnosis: 70.5 years (25,734 days); Year of diagnosis: 2000; Method of diagnosis: Surgical Resection; FIGO stage: Stage IIIC; Tumor grade: G3; Prior treatment: No.
   Pathology details: Residual tumor measurement: >20 mm.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Treatment intent type: Adjuvant; Days to treatment start: 18 days; Days to treatment end: 123 days; Number of cycles: 6; Treatment dose: 3,310 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Treatment intent type: Adjuvant; Days to treatment start: 18 days; Days to treatment end: 123 days; Number of cycles: 6; Treatment dose: 1,712 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Initial disease status: Recurrent Disease; Days to treatment start: 976 days (2.7 years); Days to treatment end: 1,084 days (3.0 years); Number of cycles: 6; Treatment dose: 1,895 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin; Initial disease status: Recurrent Disease; Days to treatment start: 976 days (2.7 years); Days to treatment end: 1,084 days (3.0 years); Number of cycles: 2; Treatment dose: 172 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Initial disease status: Recurrent Disease; Days to treatment start: 976 days (2.7 years); Days to treatment end: 1,084 days (3.0 years); Number of cycles: 6; Treatment dose: 1,660 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Topotecan; Initial disease status: Recurrent Disease; Days to treatment start: 1,270 days (3.5 years); Days to treatment end: 1,383 days (3.8 years); Number of cycles: 6; Treatment dose: 49 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Vinorelbine Tartrate; Initial disease status: Recurrent Disease; Days to treatment start: 1,270 days (3.5 years); Days to treatment end: 1,383 days (3.8 years); Number of cycles: 6; Treatment dose: 508 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Gemcitabine; Initial disease status: Progressive Disease; Days to treatment start: 1,465 days (4.0 years); Days to treatment end: 1,558 days (4.3 years); Number of cycles: 5; Treatment dose: 20,684 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Pegylated Liposomal Doxorubicin Hydrochloride; Initial disease status: Progressive Disease; Days to treatment start: 1,465 days (4.0 years); Days to treatment end: 1,558 days (4.3 years); Number of cycles: 5; Treatment dose: 277 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Initial disease status: Progressive Disease; Days to treatment start: 1,600 days (4.4 years); Days to treatment end: 1,733 days (4.7 years); Number of cycles: 17; Treatment dose: 2,275 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin; Initial disease status: Progressive Disease; Days to treatment start: 1,742 days (4.8 years); Days to treatment end: 1,791 days (4.9 years); Number of cycles: 2; Treatment dose: 168 mg; Route of administration: Intravenous.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Recurrence of diagnosis 1 (Serous cystadenocarcinoma, NOS). Age at diagnosis: 73.1 years (26,705 days); Days to diagnosis: 971 days (2.7 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Radiation Therapy, NOS, for recurrent disease.

Follow-up (2 entries)
- Day 971 (post initial treatment): Progression or recurrence: Yes; Days to recurrence: 971 days (2.7 years); Evidence of recurrence type: Convincing Image Source.
- Days to follow up: 2,218 days (6.1 years); Disease response: With Tumor.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-24-1463-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 2; Intermediate dimension: 1.3; Shortest dimension: 0.5.
  Slide TCGA-24-1463-01A-01-BS1: Section location: Bottom; Percent tumor cells: 80; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 1; Percent stromal cells: 19.
  Slide TCGA-24-1463-01A-01-TS1: Section location: Top; Percent tumor cells: 75; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 1; Percent stromal cells: 24.
- Sample TCGA-24-1463-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Serous Cystadenocarcinoma; Tumor status: With tumor; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection.
- Drug treatment 1: Pharmaceutical therapy drug name: Taxol.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 3: Pharmaceutical therapy drug name: Doxil; Therapy regimen: Progression.
- Drug treatment 5: Pharmaceutical therapy drug name: Taxol; Therapy regimen: Progression.
- Drug treatment 9: Pharmaceutical therapy drug name: Navelbine.
- Follow-up form: Treatment outcome first course: Complete Remission/Response; Tumor status: With tumor.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 2,218 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 2,218 days; disease-free interval: event (new tumor event after initially disease-free), 971 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 971 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-24-1463-01A-01D-0472-01): tumor purity 0.84, ploidy 1.75, whole-genome doublings 0.
